Somatic mutation profile of tumor specimen MBCProject_1181_T1_WES (aliquot MBCProject_1181_T1_WES_1) from CMI case MBCProject_1181, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.9 years (15,657 days).
Specimen MBCProject_1181_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c86c0e-c938-4686-9f97-ba0c69d65d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1181_SALIVA (Saliva), aliquot MBCProject_1181_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff2ccc3b-303a-4512-93bf-216014c5b1aa

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Intron 2, Splice Site 2, IGR 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1320+1G>T p.X440_splice | Splice Site (SNP) | VAF 91/265 reads (34%) | hotspot (GDC flag); catalogued as COSV55727403, COSV55730311, COSV55730426, COSV55740321; called by muse, mutect2, varscan2
- OCA2 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144812594, CM952146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1635G>C p.E545D | Missense Mutation (SNP) | VAF 24/90 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic; called by muse, varscan2
- CDH10 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV52577280, COSV52580482; called by muse, mutect2, varscan2
- CEP295NL | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs952458245, COSV53160810; called by muse, mutect2, varscan2
- DIXDC1 | c.1693C>T p.R565W (on ENST00000440460 / NM_001037954.4; = p.R354W on NM_033425.4) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs374982364; called by muse, mutect2, varscan2
- GABRB3 | c.1319C>A p.P440H | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100158267; called by muse, mutect2, varscan2
- PTEN | c.463T>G p.Y155D | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM110152, CM132267, COSV64290082, COSV64307317; called by muse, mutect2, varscan2
- SLC25A19 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 105/611 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753574313; called by muse, mutect2, varscan2
- SLC34A2 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs932836843, COSV65941946; called by muse, mutect2, varscan2
- URB1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943637689, COSV63220688; called by muse, mutect2, varscan2
- ZNF467 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.199); catalogued as COSV100118066; called by muse, mutect2, varscan2
- DEK | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DGCR2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHH3 | c.860T>C p.M287T | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RCOR3 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SELE | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF99 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 30/130 reads (23%) | called by muse, varscan2
- GFAP | c.1105C>T p.L369= | Silent (SNP) | VAF 163/413 reads (39%) | called by muse, mutect2, varscan2
- GRIN1 | c.420C>T p.T140= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as rs771424493; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAK1IP1 | c.1086A>C p.T362= | Silent (SNP) | VAF 75/283 reads (27%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.2218C>A p.R740= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV99425437; called by muse, mutect2, varscan2
- SLC6A8 | c.312C>G p.P104= | Silent (SNP) | VAF 105/435 reads (24%) | called by muse, mutect2, varscan2
- TXNRD1 | c.1143C>T p.D381= (on ENST00000525566 / NM_001093771.3; = p.D283= on NM_003330.4) | Silent (SNP) | VAF 58/237 reads (24%) | called by muse, mutect2, varscan2
- ZNF536 | c.615C>T p.R205= | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as rs745738230; called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670527 del A | 5'Flank (DEL) | VAF 18/68 reads (26%) | catalogued as rs750918355; called by mutect2, varscan2
- ARFGAP2 | c.481-69G>T | Intron (SNP) | VAF 32/136 reads (24%) | catalogued as rs752428207; called by muse, mutect2, varscan2
- PHF6 | c.*9del | 3'UTR (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- PSMD1 | c.1998+67T>A | Intron (SNP) | VAF 88/330 reads (27%) | called by muse, mutect2, varscan2
- Unknown | chr1:200343288 G>A | IGR (SNP) | VAF 52/89 reads (58%) | called by muse, mutect2, varscan2
